Somatic mutation profile of tumor specimen TCGA-HZ-7919-01A (aliquot TCGA-HZ-7919-01A-11D-2154-08) from TCGA case TCGA-HZ-7919, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 52.2 years (19,064 days).
Specimen TCGA-HZ-7919-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 452f682b-a57e-4a66-aa82-4a7431cef326.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-7919-10A (Blood Derived Normal), aliquot TCGA-HZ-7919-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/523fa9b3-0d1a-47fc-8de9-69d81ded6828

The open-access MAF lists 61 somatic variants for this specimen: 45 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 14, Nonsense Mutation 3, RNA 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 37/127 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 110/453 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61684436, COSV61688043; called by muse, mutect2, varscan2
- ALDH3A2 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 99/643 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99450070; called by muse, mutect2, varscan2
- ANGPTL7 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 136/648 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100816492; called by muse, mutect2, varscan2
- ANKRD28 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 82/437 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV101080813; called by muse, mutect2, varscan2
- BRWD3 | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 81/415 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs937178689, COSV64744346; called by muse, mutect2, varscan2
- BTG2 | c.391T>G p.S131A | Missense Mutation (SNP) | VAF 161/690 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99305864; called by muse, mutect2, varscan2
- CDH11 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 314/846 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751908119, COSV51754388, COSV99219492; called by muse, mutect2, varscan2
- COL6A2 | c.1793T>A p.V598E | Missense Mutation (SNP) | VAF 34/1168 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100153928; called by muse, mutect2
- DEK | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99789014; called by muse, mutect2, varscan2
- DUOXA2 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs767813041, COSV99973366; called by muse, mutect2, varscan2
- FBXO45 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61146609; called by muse, mutect2, varscan2
- FLNA | c.5135A>G p.Y1712C (on ENST00000369850 / NM_001110556.2; = p.Y1704C on NM_001456.3) | Missense Mutation (SNP) | VAF 113/458 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774938; called by muse, mutect2, varscan2
- GLCE | c.647A>C p.Q216P | Missense Mutation (SNP) | VAF 122/492 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99962511; called by muse, mutect2, varscan2
- GREB1 | c.2545C>T p.H849Y | Missense Mutation (SNP) | VAF 366/987 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as COSV99303375; called by muse, mutect2, varscan2
- INPP5F | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 86/366 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV100740278; called by muse, mutect2, varscan2
- ITGAL | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 151/345 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs749508499, COSV63319940; called by muse, mutect2, varscan2
- KCNA5 | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs779699586, COSV52906823; called by muse, mutect2, varscan2
- KIF1B | c.4546G>A p.E1516K (on ENST00000377086 / NM_001365952.1; = p.E1470K on NM_015074.3) | Missense Mutation (SNP) | VAF 67/357 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.193); catalogued as COSV99823803; called by muse, mutect2, varscan2
- KRT4 | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 92/485 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99543092; called by muse, varscan2
- LMTK3 | c.3652C>T p.Q1218* | Nonsense Mutation (SNP) | VAF 95/527 reads (18%) | catalogued as COSV99540887; called by muse, mutect2, varscan2
- MARK1 | c.202A>C p.K68Q | Missense Mutation (SNP) | VAF 138/527 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100857396; called by muse, mutect2, varscan2
- MAST4 | c.6300G>C p.E2100D (on ENST00000403625 / NM_001164664.2; = p.E1911D on NM_015183.3) | Missense Mutation (SNP) | VAF 86/437 reads (20%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as COSV99845011; called by muse, mutect2, varscan2
- MBTPS1 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 107/524 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as rs773874587, COSV100597691; called by muse, mutect2, varscan2
- METTL17 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 113/614 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs769704814, COSV100228302; called by muse, mutect2, varscan2
- MRPS2 | c.183G>C p.K61N | Missense Mutation (SNP) | VAF 125/670 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV99613573; called by muse, mutect2, varscan2
- MXRA7 | c.498G>C p.Q166H | Missense Mutation (SNP) | VAF 256/1074 reads (24%) | PolyPhen benign (0.037); catalogued as COSV100869791; called by muse, mutect2, varscan2
- NT5C3B | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 184/1197 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs1382221058, COSV99505272; called by muse, mutect2, varscan2
- OR5T3 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 93/417 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV57382505; called by muse, mutect2, varscan2
- PKD1L1 | c.6730G>C p.E2244Q | Missense Mutation (SNP) | VAF 107/503 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV99220736; called by muse, mutect2, varscan2
- PLEKHH2 | c.3051G>C p.Q1017H | Missense Mutation (SNP) | VAF 287/743 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99174935; called by muse, mutect2, varscan2
- PRIM1 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1290406998, COSV100590436; called by muse, mutect2
- RBBP8 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 322/979 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100507558; called by muse, mutect2, varscan2
- RSBN1 | c.1264C>G p.L422V | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99793440; called by muse, mutect2, varscan2
- SH3GL1 | c.465+1G>A p.X155_splice | Splice Site (SNP) | VAF 52/250 reads (21%) | catalogued as COSV99515273; called by muse, mutect2, varscan2
- SIDT2 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 125/718 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.482); catalogued as COSV99638114; called by muse, mutect2, varscan2
- SLC2A9 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 112/518 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99305153; called by muse, mutect2, varscan2
- SPTAN1 | c.5846C>G p.S1949* | Nonsense Mutation (SNP) | VAF 59/280 reads (21%) | catalogued as COSV100823799; called by muse, mutect2, varscan2
- ST3GAL2 | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 144/411 reads (35%) | PolyPhen possibly damaging (0.858); catalogued as COSV100735725; called by muse, mutect2, varscan2
- THSD4 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs183837037, COSV99966369; called by muse, mutect2
- TTLL5 | c.3445C>T p.Q1149* | Nonsense Mutation (SNP) | VAF 183/870 reads (21%) | catalogued as rs1174217234, COSV100091024; called by muse, mutect2, varscan2
- UBR2 | c.335G>C p.C112S | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100868635; called by muse, mutect2
- ZNF174 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 32/705 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99237595; called by muse, mutect2
- ENTHD1 | c.370T>G p.S124A | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.429); called by muse, mutect2
- PALMD | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 105/722 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- AKAP13 | c.5022T>C p.F1674= (on ENST00000394518 / NM_007200.5; = p.F1678= on NM_006738.6) | Silent (SNP) | VAF 90/531 reads (17%) | catalogued as COSV100774204; called by muse, mutect2, varscan2
- BNC1 | c.2505G>A p.T835= | Silent (SNP) | VAF 81/478 reads (17%) | catalogued as rs1230765578, COSV100597348; called by muse, mutect2, varscan2
- EPHB4 | c.1554C>T p.F518= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as rs148818692; called by muse, mutect2, varscan2
- ESAM | c.600A>G p.P200= | Silent (SNP) | VAF 59/244 reads (24%) | catalogued as COSV99631998; called by muse, mutect2, varscan2
- FANCA | c.2037G>A p.V679= | Silent (SNP) | VAF 155/367 reads (42%) | catalogued as COSV101225010; called by muse, mutect2, varscan2
- PCDHGA6 | c.822C>T p.H274= | Silent (SNP) | VAF 44/233 reads (19%) | catalogued as rs756655009, COSV99542643; called by muse, mutect2, varscan2
- RIN2 | c.2568C>G p.L856= (on ENST00000255006 / NM_001242581.1; = p.L807= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 150/908 reads (17%) | catalogued as COSV99657527; called by muse, mutect2, varscan2
- SLC25A6 | c.546G>A p.Q182= | Silent (SNP) | VAF 152/851 reads (18%) | catalogued as rs774126984, COSV101195475; called by muse, mutect2, varscan2
- SLC5A1 | c.423C>A p.I141= | Silent (SNP) | VAF 101/522 reads (19%) | catalogued as COSV99833605; called by muse, mutect2, varscan2
- SPHK2 | c.387C>T p.R129= | Silent (SNP) | VAF 37/138 reads (27%) | catalogued as COSV99709476; called by muse, mutect2, varscan2
- TAAR9 | c.210G>C p.L70= | Silent (SNP) | VAF 77/324 reads (24%) | catalogued as COSV101453367; called by muse, mutect2, varscan2
- TCP11L1 | c.1377G>A p.Q459= | Silent (SNP) | VAF 213/1165 reads (18%) | catalogued as COSV100178268; called by muse, mutect2, varscan2
- TOX2 | c.1188C>T p.G396= (on ENST00000358131 / NM_001098798.2; = p.G372= on NM_032883.3) | Silent (SNP) | VAF 50/300 reads (17%) | catalogued as rs951078230, COSV100364277; called by muse, mutect2, varscan2
- ZER1 | c.1149C>T p.R383= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV99402254; called by muse, mutect2
- FAM183BP | n.996C>T | RNA (SNP) | VAF 125/489 reads (26%) | catalogued as rs772909023; called by muse, mutect2, varscan2
- NRP1 | c.1924+2087C>G | Intron (SNP) | VAF 67/468 reads (14%) | called by muse, mutect2, varscan2
